Gene-level copy-number profile of tumor specimen TCGA-D3-A8GE-06A from TCGA case TCGA-D3-A8GE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 26.1 years (9,517 days).
Specimen TCGA-D3-A8GE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.cf6caf52-0b4f-44f9-bd29-9d805352c447.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A8GE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/841ce9ab-fe41-4bff-85ab-6285d6210268

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 2,559; copy number 2: 57,247.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A8GE-06A-11D-A371-01): tumor purity 0.6, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 173. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
